Gene-level copy-number profile of tumor specimen BLGSP-71-17-00238-01A from CGCI case BLGSP-71-17-00238, project CGCI-BLGSP (Burkitt Lymphoma Genome Sequencing Project). Sex at birth: male; Vital status: Alive; Primary diagnosis: Burkitt lymphoma, NOS (Includes all variants); Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 66.0 years (24,111 days).
Specimen BLGSP-71-17-00238-01A: Sample type: Slides; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file af463df6-dccd-4e1b-8770-e18117cfa51c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator BLGSP-71-17-00238-99A (granulocytes); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,818 have no estimate.
https://portal.gdc.cancer.gov/files/27e140c4-eeb8-4515-9d5b-3c4def98fec7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 438; copy number 1: 4,231; copy number 2: 51,058; copy number 3: 2,511; copy number 4: 527; copy number 5: 36; copy number 6: 1; copy number 8: 3.

Homozygous deletions (total copy number 0; autosomes only): 215 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:2,315,040–2,817,767, 26 genes: AL590822.3, MORN1, AL589739.1, AL513477.1, AL513477.2, RER1, PEX10, PLCH2, AL139246.1, AL139246.4, PANK4, HES5, AL139246.5, TNFRSF14-AS1, TNFRSF14, AL139246.2, AL139246.3, PRXL2B, MMEL1, MMEL1-AS1, TTC34, AC242022.2, AC242022.1, AL592464.2, AL592464.3, AL592464.1.
- chr1:5,990,927–6,394,391, 12 genes (within-gene range 0–2): KCNAB2, CHD5, AL031847.1, RPL22, RNF207-AS1, RNF207, ICMT, LINC00337, HES3, GPR153, ACOT7, AL031848.2.
- chr2:88,857,161–89,245,596, 38 genes (within-gene range 0–2): IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17, IGKV2-18, IGKV2-19, IGKV3-20, IGKV6-21, IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, IGKV2-26, AC244255.1, IGKV1-27, IGKV2-28, IGKV2-29, IGKV2-30.
- chr4:8,846,076–8,871,839, 2 genes: HMX1, AC116612.1.
- chr5:1,050,384–1,112,063, 2 genes: SLC12A7, MIR4635.
- chr8:142,449,430–142,545,009, 1 gene: ADGRB1.
- chr14:105,620,506–106,481,706, 132 genes (within-gene range 0–2) (broad region; genes not listed).
- chr14:106,531,141–106,538,344, 2 genes (within-gene range 0–3): IGHVIII-47-1, IGHV3-48.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 40 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:198,597,724–198,757,476, 4 genes, copy number 5: AL157402.1, PTPRC, AL157402.2, PEBP1P3.
- chr2:89,266,494–89,600,680, 9 genes, copy number 5: IGKV1-33, IGKV3-34, IGKV1-35, IGKV2-36, IGKV1-37, IGKV2-38, IGKV1-39, IGKV2-40, 5S_rRNA.
- chr2:157,414,619–157,488,961, 1 gene, copy number 5: CYTIP.
- chr2:164,653,624–164,843,679, 1 gene, copy number 5 (within-gene range 3–5): COBLL1.
- chr2:164,858,432–164,858,546, 1 gene, copy number 5: RNA5SP110.
- chr2:196,133,583–196,176,503, 2 genes, copy number 5: STK17B, AC114760.2.
- chr2:237,627,587–237,813,682, 2 genes, copy number 5 (within-gene range 2–5): LRRFIP1, AC012076.1.
- chr4:40,191,053–40,246,967, 1 gene, copy number 5: RHOH.
- chr7:30,284,597–30,367,689, 3 genes, copy number 5 (within-gene range 3–5): ZNRF2, MIR550A1, MIR550B1.
- chr11:9,664,077–9,752,993, 2 genes, copy number 5: SWAP70, RN7SKP50.
- chr11:65,445,541–65,488,896, 4 genes, copy number 5: AP000769.4, AP000769.1, LINC02736, AP000769.6.
- chr14:18,333,726–18,419,273, 4 genes, copy number 6–8: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6.
- chr14:106,850,885–106,879,812, 6 genes, copy number 5: MIR5195, IGHV5-78, IGHVII-78-1, IGHV3-79, IGHV7-81, IGHVIII-82.

Autosomal genes at a single copy (total copy number 1): 1,678. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
